TCGA case TCGA-90-7766 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: ABS - IUPUI. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3fdf941e-40ec-43b6-b6e3-31a0861bd5b8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Alive.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 66.7 years (24,354 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 289 days.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the female genital tract (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 67.5 years (24,643 days); Days to diagnosis: 289 days; Prior treatment: Yes.

Follow-up (2 entries)
- Days to follow up: 47 days; Disease response: Tumor Free.
- Day 289 (post initial treatment): Disease response: With Tumor; Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 289 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 30; Tobacco smoking onset year: 1981.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-90-7766-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-90-7766-01A-01-BS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 61; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-90-7766-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-90-7766-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.3; Intermediate dimension: 1; Shortest dimension: 0.6.
  Slide TCGA-90-7766-11A-01-TS1: Section location: Top; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Progressive Disease; Tumor status: With tumor.
- Follow-up form, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: gynecological (not otherwise specified).

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Prior malignancy of a gynecological cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 289 days; disease-specific survival: no event (censored), 289 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 289 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-90-7766-01A-21D-2121-01): tumor purity 0.59, ploidy 1.83, whole-genome doublings 0.
